Gene-level copy-number profile of tumor specimen TCGA-60-2714-01A from TCGA case TCGA-60-2714, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.2 years (24,169 days).
Specimen TCGA-60-2714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a3b60ae0-8a58-4c89-acb8-df47d2e65d23.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2714-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19f6e985-31a7-4c94-9d76-fba2c5bd8929

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,960; copy number 3: 10,627; copy number 4: 14,430; copy number 5: 12,843; copy number 6: 9,247; copy number 7: 1,936; copy number 8: 1,301; copy number 9: 3,372; copy number 11: 349; copy number 12: 1,193; copy number 13: 219; copy number 14: 118; copy number 15: 135; copy number 16: 59; copy number 17: 13; copy number 25: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2714-01A-01D-0844-01): tumor purity 0.34, ploidy 5.13, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,466 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–52,097,299, 8 genes, copy number 25: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18.
- chr4:142,514,446–145,559,176, 49 genes, copy number 12–15 (within-gene range 3–15): AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3, AC098588.2, AC106871.1, KRT18P51, HHIP-AS1, HHIP, AC098588.1, ANAPC10, HSPD1P5, AC109811.1, AC109811.2, RN7SKP235, ABCE1, OTUD4, Y_RNA, RPS23P4, LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1.
- chr7:70,972–159,233,377, 3,014 genes, copy number 9 (broad region; genes not listed).
- chr8:63,215,981–70,669,185, 119 genes, copy number 11 (broad region; genes not listed).
- chr8:78,805,293–78,956,082, 1 gene, copy number 11 (within-gene range 8–11): AC083837.1.
- chr8:79,259,402–145,066,685, 1,050 genes, copy number 11–12 (broad region; genes not listed).
- chr14:27,258,717–41,904,549, 219 genes, copy number 13 (broad region; genes not listed).
- chr16:3,037,400–21,159,441, 479 genes, copy number 12–17 (within-gene range 4–17) (broad region; genes not listed).
- chr16:52,005,487–52,280,638, 8 genes, copy number 9 (within-gene range 4–9): C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22.
- chr21:10,328,411–23,131,206, 169 genes, copy number 15–16 (broad region; genes not listed).
- chr21:34,205,055–46,665,124, 350 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
